Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9KC, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9KC-01A (Primary Tumor).

ICD-03
Carcinoma, papillary renal cell 8260/3
Site: Kidney NOS C64.9
5/6/14

Papillary Renal Cell Carcinoma, Type I, well differentiated. Maximum dimensions: Piece 1 4.2 cm, piece 2 0.1 cm. The kidney parenchyma presents with a high-grade interstitial fibrosys and ectatic vasculature at the borders

Stage: pT1b, R0

Grade: G1

ICD-0-Code: 8260/3

Laterality = (L)

Source: NCI Genomic Data Commons file 0c416014-f059-4853-829e-74caece363fe (TCGA-5P-A9KC.50F41977-E4BF-406C-A5D4-DCBE9D5992F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).